Somatic mutation profile of cancer-model specimen HCM-CSHL-0464-C50-85D (3D Organoid, passage 11; aliquot HCM-CSHL-0464-C50-85D-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0464-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.0 years (15,330 days).
Specimen HCM-CSHL-0464-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 621086b1-18ce-430a-81dd-bff6f91a36f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0464-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0464-C50-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f497011a-e865-46d3-8a7a-c9478d309c88

The open-access MAF lists 90 somatic variants for this specimen: 64 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 23, Nonsense Mutation 4, Frame Shift Del 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, In Frame Ins 1, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT83 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1438087533, CM151774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 200/200 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.987C>A p.I329= | Splice Region (SNP) | VAF 92/204 reads (45%) | catalogued as rs1323374413; called by muse, mutect2, varscan2
- AGAP2 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 134/365 reads (37%) | catalogued as rs1555199972; called by muse, mutect2, varscan2
- APCDD1L | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 178/2761 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs765708116; called by muse, mutect2
- BACE2 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754593712; called by muse, mutect2, varscan2
- BCAS1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 272/1463 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV101006384; called by muse, varscan2
- C16orf90 | c.103G>A p.G35S (on ENST00000399645 / NM_001353385.2; = p.G26S on NM_001080524.2) | Missense Mutation (SNP) | VAF 71/630 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs372652628; called by muse, mutect2, varscan2
- CAMK4 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV56660873; called by muse, mutect2, varscan2
- CDH23 | c.5443G>A p.A1815T | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.381); catalogued as rs199581934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPF | c.6228G>T p.Q2076H | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as COSV65275083; called by muse, mutect2, varscan2
- COL8A1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 78/400 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV53744013; called by muse, mutect2, varscan2
- ERAP2 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 87/332 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs545472330, COSV65941200; called by muse, mutect2, varscan2
- GMEB2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 754/1342 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs141199322; called by muse, varscan2
- GPR119 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 138/498 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.07); catalogued as COSV52275328, COSV52275642; called by muse, mutect2, varscan2
- H2AC16 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs778934233, COSV100511411, COSV58899804; called by muse, mutect2, varscan2
- KDM4D | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 98/449 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs201708087, COSV58636128; called by muse, mutect2, varscan2
- KIAA0408 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 221/930 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV64115887; called by muse, mutect2, varscan2
- LCA5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs568193819, COSV63971388; called by muse, mutect2, varscan2
- MAP3K1 | c.2326_2327del p.I776Cfs*4 | Frame Shift Del (DEL) | VAF 69/299 reads (23%) | catalogued as rs1311306052; called by pindel, varscan2
- MRPL33 | c.184dup p.I62Nfs*30 | Frame Shift Ins (INS) | VAF 44/244 reads (18%) | catalogued as rs1474512733; called by mutect2, varscan2
- OSBPL5 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867268261; called by muse, mutect2, varscan2
- PCDHA4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs782583105, COSV63544869; called by muse, varscan2
- PLPP5 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 94/525 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs951786625, COSV68157222; called by muse, mutect2, varscan2
- PRICKLE1 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs151332996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDNL | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1336997230, COSV62478398; called by muse, varscan2
- RASIP1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 170/692 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.117); catalogued as rs1430096957; called by muse, mutect2, varscan2
- SH2D3A | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 146/394 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs774385767; called by muse, mutect2, varscan2
- SLC9A9 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 63/272 reads (23%) | catalogued as COSV57219608; called by muse, mutect2, varscan2
- SORCS2 | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV61162707; called by muse, mutect2, varscan2
- TCHHL1 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 123/527 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.166); catalogued as COSV64285697; called by muse, mutect2, varscan2
- TMEM132D | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70602945; called by muse, mutect2, varscan2
- VWF | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 159/166 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs751311885, COSV99777620; called by muse, mutect2, varscan2
- ADAM8 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 123/237 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDC6 | c.1250G>A p.C417Y | Missense Mutation (SNP) | VAF 166/816 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.074); called by muse, varscan2
- CDC6 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 372/1862 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, varscan2
- CFAP47 | c.6679C>G p.R2227G | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A4 | c.4093G>T p.E1365* | Nonsense Mutation (SNP) | VAF 62/235 reads (26%) | called by muse, mutect2, varscan2
- CYP4F22 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DCAF13 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 30/706 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECEL1 | c.1043A>C p.Q348P | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FCRL1 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- FOXQ1 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, varscan2
- GPR87 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 127/511 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN3 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 245/386 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIA3 | c.110-1G>A p.X37_splice | Splice Site (SNP) | VAF 79/252 reads (31%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2375C>A p.S792Y | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KMT2D | c.10661G>C p.R3554P | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA2 | c.8833G>A p.D2945N | Missense Mutation (SNP) | VAF 70/444 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.08); called by muse, varscan2
- MMP21 | c.1363T>G p.F455V | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- NUB1 | c.790C>G p.H264D | Missense Mutation (SNP) | VAF 237/404 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX7 | c.3562C>A p.Q1188K (on ENST00000559447 / NM_001368074.1; = p.Q1285K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/497 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RIMS1 | c.2753_2767dup p.P922_P923insLGVVP | In Frame Ins (INS) | VAF 46/219 reads (21%) | called by mutect2, varscan2
- RUFY4 | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC9A7 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 176/738 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, varscan2
- SYNPO2L | c.2662C>T p.R888C (on ENST00000394810 / NM_001114133.3; = p.R664C on NM_024875.5) | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TASOR | c.1951A>T p.K651* (on ENST00000355628 / NM_001365636.2; = p.K255* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- TBX3 | c.1157_1169del p.G386Afs*242 (on ENST00000257566 / NM_016569.4; = p.G366Afs*242 on NM_005996.4) | Frame Shift Del (DEL) | VAF 256/452 reads (57%) | called by mutect2, pindel, varscan2
- THADA | c.2911T>C p.S971P | Missense Mutation (SNP) | VAF 167/482 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA6 | c.759G>C p.M253I | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ZAP70 | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 22/614 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ZFP36L1 | c.353A>T p.E118V | Missense Mutation (SNP) | VAF 265/393 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF785 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- AKNA | c.387C>T p.L129= | Silent (SNP) | VAF 120/414 reads (29%) | catalogued as rs767224437, COSV56312931; called by muse, mutect2, varscan2
- ALPK3 | c.1788G>A p.G596= | Silent (SNP) | VAF 83/503 reads (17%) | catalogued as rs1044264701, COSV51938053; called by muse, mutect2, varscan2
- BCAS1 | c.375C>T p.S125= | Silent (SNP) | VAF 292/1324 reads (22%) | called by muse, varscan2
- CARD11 | c.597C>T p.D199= | Silent (SNP) | VAF 363/600 reads (61%) | catalogued as COSV62718034; called by muse, mutect2, varscan2
- DGKI | c.195G>A p.A65= | Silent (SNP) | VAF 60/425 reads (14%) | called by muse, mutect2, varscan2
- DUOX2 | c.2022C>T p.V674= | Silent (SNP) | VAF 230/844 reads (27%) | catalogued as rs1171054411, COSV101199888; called by muse, mutect2, varscan2
- EMID1 | c.51G>C p.P17= | Silent (SNP) | VAF 117/234 reads (50%) | called by muse, mutect2, varscan2
- FAM81A | c.447G>A p.E149= | Silent (SNP) | VAF 76/386 reads (20%) | called by muse, mutect2, varscan2
- FBXW9 | c.1125G>A p.Q375= (on ENST00000587955; = p.Q355= on NM_032301.3) | Silent (SNP) | VAF 79/304 reads (26%) | called by muse, mutect2, varscan2
- FLNA | c.5271G>T p.L1757= (on ENST00000369850 / NM_001110556.2; = p.L1749= on NM_001456.3) | Silent (SNP) | VAF 152/466 reads (33%) | called by muse, mutect2, varscan2
- FLNB | c.3589C>T p.L1197= | Silent (SNP) | VAF 101/217 reads (47%) | called by muse, mutect2, varscan2
- GRIN2B | c.2907G>A p.T969= | Silent (SNP) | VAF 121/282 reads (43%) | catalogued as rs199536073, COSV74208002; called by muse, mutect2, varscan2
- INTS4 | c.774C>T p.V258= | Silent (SNP) | VAF 72/344 reads (21%) | catalogued as rs762153928; called by muse, mutect2, varscan2
- KIAA1210 | c.1932C>G p.S644= | Silent (SNP) | VAF 100/693 reads (14%) | called by muse, mutect2, varscan2
- MX2 | c.825G>A p.A275= | Silent (SNP) | VAF 91/479 reads (19%) | catalogued as rs750143179; called by muse, mutect2, varscan2
- PAQR7 | c.1038G>A p.K346= | Silent (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- PTGDR | c.177G>T p.S59= | Silent (SNP) | VAF 31/488 reads (6%) | catalogued as rs1447995413; called by muse, mutect2
- SFTPD | c.465G>C p.S155= | Silent (SNP) | VAF 119/371 reads (32%) | catalogued as COSV64853860; called by muse, mutect2, varscan2
- SLC35G1 | c.423T>C p.S141= (on ENST00000427197 / NM_001134658.3; = p.S140= on NM_153226.4) | Silent (SNP) | VAF 92/285 reads (32%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.75G>C p.A25= | Silent (SNP) | VAF 120/313 reads (38%) | catalogued as COSV100195015; called by muse, mutect2, varscan2
- TRAV30 | c.90C>A p.A30= | Silent (SNP) | VAF 75/266 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.81570G>A p.L27190= (on ENST00000591111; = p.L19766= on NM_003319.4) | Silent (SNP) | VAF 100/328 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.54687A>G p.V18229= (on ENST00000591111; = p.V10805= on NM_003319.4) | Silent (SNP) | VAF 72/182 reads (40%) | called by muse, mutect2, varscan2
- KLHL33 | c.-89G>T | 5'UTR (SNP) | VAF 107/424 reads (25%) | catalogued as COSV60726989; called by muse, mutect2, varscan2
- NBPF25P | n.1817C>T | RNA (SNP) | VAF 165/612 reads (27%) | catalogued as rs1308894544; called by muse, mutect2, varscan2
- SDC3 | c.*3675_*3684delinsTTGTTTG | 3'UTR (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2*
